Somatic mutation profile of tumor specimen 0DZWVX from CCDI case PBCUPH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0DZWVX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6e93a31-5d1f-4243-8bb9-2e413337e99a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZWWD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71a05e8e-fde3-4be1-a2a1-f2c1e65bc02c

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EEPD1 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 148/420 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs759289879, COSV54200747; called by muse, mutect2
- MCF2L2 | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767614039, COSV61063150; called by muse, mutect2
- VN1R4 | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 58/640 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.342); catalogued as rs138349340; called by muse, mutect2
- LAMC1 | c.1147C>G p.R383G | Missense Mutation (SNP) | VAF 214/677 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- MAGEC3 | c.1672A>C p.I558L | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.104); called by muse, mutect2
- NRXN3 | c.2517G>A p.M839I (on ENST00000335750 / NM_001330195.2; = p.M466I on NM_004796.6) | Missense Mutation (SNP) | VAF 82/475 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- OR5B21 | c.167C>A p.P56Q | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAP1L3 | c.-35C>T | 5'UTR (SNP) | VAF 21/230 reads (9%) | catalogued as COSV59078364; called by muse, mutect2
